Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7263, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7263-01A (Primary Tumor).

[page 1 of 2]
** Case imported from legacy computer system. The format of this report does not match the original case. **
** For cases prior to [REDACTED] the section "SPECIMEN" may have been added. **

SUPPLEMENTAL REPORT

RECD: [REDACTED] PATH: [REDACTED] DOB: [REDACTED]
[REDACTED] FINAL DATE: [REDACTED]
CONSULTANT: [REDACTED] TO: [REDACTED]
PHOTO: NO
DX COMPLETED: [REDACTED]
[REDACTED] CLINIC COPY TO:

SUPPLEMENTAL REPORT

DIAGNOSIS :

- (A) RESECTION OF FIBULOGRAFT, LEFT PARTIAL GLOSSECTOMY:
INVASIVE WELL DIFFERENTIATED SQUAMOUS CARCINOMA INVOLVING FOCALLY
FIBULOGRAFT. (SEE COMMENT)
Bone margins of resection free of tumor.
COMMENT: This supplemental report is being issued to give the results of
sections submitted for decalcification.
SECTION CODE: A16, A17, representative sections of graft (fibula); A18,
perpendicular right margin of resection inked in black; A19-A23, left margin
of resection inked in red, perpendicular sections. [REDACTED]

DIAGNOSIS

- (A) RESECTION OF FIBULOGRAFT, LEFT PARTIAL GLOSSECTOMY:
INVASIVE WELL DIFFERENTIATED SQUAMOUS CARCINOMA INVOLVING TONGUE AND
FLOOR OF MOUTH. (SEE COMMENT)
CARCINOMA EXTENDING FOCALLY TO THE LEFT ANTEROLATERAL FLOOR OF MOUTH
MUCOSAL MARGIN OF RESECTION. (SEE COMMENT)
Other margins of resection free of tumor.
Sections of bone pending decalcification. Supplemental report to
follow.
(B) TEETH:
Multiple teeth and fragments of teeth, gross diagnosis only.

COMMENT

The tumor (3.0 x 3.0 x 2.3 cm) involves the anterior base of tongue
and adjacent floor of mouth. Tumor extends focally to the inked left lateral
anterior mucosal margin of resection. Perineural invasion is present. No
unequivocal lymphatic/vascular invasion is present.
[REDACTED]

SPECIMEN

- (A) RESECTION OF FIBULOGRAFT, LEFT PARTIAL GLOSSECTOMY:
(B) TEETH:

SNOMED CODES

[page 2 of 2]
T-53000,M-80703

Source: NCI Genomic Data Commons file 2aa12cc6-34ea-4e04-ad49-e8a318ef338c (TCGA-CV-7263.B0D9A028-8029-4F50-AEAD-96B023DE5920.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).